Somatic mutation profile of tumor specimen TCGA-DX-A6Z0-01A (aliquot TCGA-DX-A6Z0-01A-13D-A36J-09) from TCGA case TCGA-DX-A6Z0, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Fibromyxosarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 78.8 years (28,796 days).
Specimen TCGA-DX-A6Z0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 92c25906-7405-4b6d-9032-e33f3d69c3b6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A6Z0-10B (Blood Derived Normal), aliquot TCGA-DX-A6Z0-10B-01D-A36M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/303f62b3-bf72-4b8d-87fa-62496bdbfae5

The open-access MAF lists 42 somatic variants for this specimen: 32 protein-altering or splice-affecting, 10 silent.
By variant classification: Missense Mutation 25, Silent 10, Splice Region 3, Frame Shift Ins 2, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAM8 | c.2342C>T p.P781L | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as COSV101291746; called by muse, mutect2
- ADGRG5 | c.1485C>T p.Y495= | Splice Region (SNP) | VAF 8/34 reads (24%) | catalogued as rs370635864, COSV61083030; called by muse, mutect2, varscan2
- ANGPTL4 | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 42/95 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.079); catalogued as rs756775279, COSV100035266; called by muse, mutect2, varscan2
- ASTN2 | c.3515T>C p.V1172A (on ENST00000313400 / NM_001365069.1; = p.V1121A on NM_014010.5) | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV99941694; called by muse, mutect2
- CBLL2 | c.265G>A p.G89R | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.305); catalogued as COSV60368352, COSV60369991; called by muse, mutect2, varscan2
- COL4A6 | c.3125G>T p.G1042V | Missense Mutation (SNP) | VAF 14/210 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100565019; called by muse, mutect2
- COL7A1 | c.3894G>A p.R1298= | Splice Region (SNP) | VAF 13/79 reads (16%) | catalogued as COSV100097676; called by muse, mutect2, varscan2
- EGFL8 | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100247094; called by muse, mutect2, varscan2
- FAM47A | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 50/307 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.096); catalogued as COSV100650068; called by muse, varscan2
- FGD5 | c.3523G>T p.A1175S | Missense Mutation (SNP) | VAF 77/111 reads (69%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.665); catalogued as COSV99549236; called by muse, mutect2, varscan2
- FSCB | c.83C>T p.T28I | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.511); catalogued as COSV100469865; called by muse, mutect2, varscan2
- GIMAP8 | c.1960G>A p.E654K | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as rs750008473, COSV56231017; called by muse, mutect2, varscan2
- HDAC5 | c.2632C>G p.Q878E | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.832); catalogued as COSV99291371; called by muse, mutect2, varscan2
- IGDCC3 | c.2120G>A p.R707Q | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0); catalogued as rs371434447; called by muse, mutect2, varscan2
- INPP5D | c.1306G>A p.D436N (on ENST00000445964 / NM_001017915.3; = p.D435N on NM_005541.5) | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV100856918; called by muse, mutect2, varscan2
- OR8D1 | c.816G>T p.K272N | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV100766676; called by muse, mutect2, varscan2
- P2RY4 | c.47C>A p.P16Q | Missense Mutation (SNP) | VAF 13/138 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs781633256, COSV100997053; called by muse, mutect2
- PASD1 | c.1566G>C p.Q522H | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100949623, COSV64854763; called by muse, mutect2, varscan2
- PCDHB1 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 31/82 reads (38%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1554267318, COSV60633061; called by muse, mutect2, varscan2
- PDE1C | c.13A>G p.T5A | Missense Mutation (SNP) | VAF 38/143 reads (27%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.038); catalogued as rs746912389, COSV100373782; called by muse, mutect2, varscan2
- PGM5 | c.1149C>A p.S383R | Missense Mutation (SNP) | VAF 22/59 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV101123560; called by muse, mutect2, varscan2
- PIP5K1B | c.58dup p.T20Nfs*3 | Frame Shift Ins (INS) | VAF 28/82 reads (34%) | catalogued as rs1311542883; called by mutect2, pindel, varscan2
- PTGIR | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0.028); catalogued as rs200508770, COSV52193534; called by muse, mutect2, varscan2
- RELN | c.6646C>T p.R2216* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as rs1368573599, COSV100633984, COSV59033733; called by muse, mutect2, varscan2
- SLC12A5 | c.923+1G>A p.X308_splice (on ENST00000454036 / NM_001134771.2; = p.X285_splice on NM_020708.5) | Splice Site (SNP) | VAF 17/53 reads (32%) | catalogued as rs142641765, COSV99715688; called by muse, mutect2, varscan2
- SOX30 | c.1458G>T p.Q486H | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as COSV99398777; called by muse, mutect2, varscan2
- TBC1D5 | c.825G>A p.G275= | Splice Region (SNP) | VAF 8/88 reads (9%) | catalogued as COSV99511902; called by muse, mutect2
- TDRD1 | c.715G>A p.V239I | Missense Mutation (SNP) | VAF 38/98 reads (39%) | SIFT tolerated (0.35); PolyPhen benign (0.022); catalogued as COSV99315127; called by muse, mutect2, varscan2
- TNFRSF21 | c.1765G>A p.V589I | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99730226; called by muse, mutect2, varscan2
- TP53 | c.859_863dup p.N288Kfs*59 | Frame Shift Ins (INS) | VAF 43/73 reads (59%) | catalogued as COSV99387464; called by mutect2, varscan2
- USH2A | c.836C>A p.A279E | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as COSV100242535; called by muse, mutect2, varscan2
- ZNF740 | c.410G>A p.R137H | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs769633666, COSV57240322; called by muse, mutect2, varscan2
- ARAP2 | c.1248A>C p.S416= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV100395246; called by muse, mutect2, varscan2
- CCDC27 | c.1218G>A p.S406= | Silent (SNP) | VAF 23/96 reads (24%) | catalogued as rs201495912; called by muse, mutect2, varscan2
- COL9A1 | c.1044G>T p.V348= | Silent (SNP) | VAF 6/144 reads (4%) | called by muse, mutect2
- EPOR | c.894C>T p.T298= | Silent (SNP) | VAF 21/100 reads (21%) | catalogued as COSV99710303; called by muse, mutect2, varscan2
- EVI5L | c.819G>A p.S273= | Silent (SNP) | VAF 39/136 reads (29%) | catalogued as rs761773660, COSV54483878; called by muse, mutect2, varscan2
- FBN3 | c.1611C>T p.T537= | Silent (SNP) | VAF 87/161 reads (54%) | catalogued as COSV54455525; called by muse, mutect2, varscan2
- KMT2C | c.2349C>T p.S783= | Silent (SNP) | VAF 15/201 reads (7%) | catalogued as COSV100076366, COSV51499757, COSV51514859; called by muse, mutect2
- NELL1 | c.609C>T p.I203= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as rs866887036, COSV54266168; called by muse, mutect2, varscan2
- PRPF31 | c.279C>T p.I93= | Silent (SNP) | VAF 11/49 reads (22%) | catalogued as rs759742223, COSV100320124; called by muse, mutect2, varscan2
- ZNF12 | c.279G>A p.Q93= | Silent (SNP) | VAF 8/87 reads (9%) | catalogued as COSV100703886; called by muse, mutect2
